FM case AD4376 — Foundation Medicine Adult Cancer Clinical Dataset (FM-AD)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Squamous Cell Neoplasms; Primary site: Bronchus and lung.
https://portal.gdc.cancer.gov/cases/55f91365-edc6-415a-884f-3601d91a1602

Male, 62.6 years: Squamous cell carcinoma, NOS (ICD-O-3 8070/3) of the lung; metastasis biopsied or resected from the lymph node. Tumor nuclei on the sequenced sample's slide: 40% (pathologist estimate recorded by GDC). Sample type: Metastatic.
